Somatic mutation profile of tumor specimen TCGA-WH-A86K-01A (aliquot TCGA-WH-A86K-01A-11D-A36O-08) from TCGA case TCGA-WH-A86K, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 65.9 years (24,055 days).
Specimen TCGA-WH-A86K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65abfb9b-137c-404e-ae9b-75f90a2e3faa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WH-A86K-10A (Blood Derived Normal), aliquot TCGA-WH-A86K-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea7ad6fb-7553-4fb5-81cb-fb437b90031f

The open-access MAF lists 42 somatic variants for this specimen: 28 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 11, Frame Shift Del 3, Nonsense Mutation 2, Splice Region 1, 3'UTR 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/78 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACTL10 | c.299G>C p.R100P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99865170; called by muse, mutect2, varscan2
- ARFGEF1 | c.3799C>G p.Q1267E | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51613996, COSV99144732; called by muse, mutect2, varscan2
- CD33 | c.470A>G p.H157R | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV99220785; called by mutect2, varscan2
- CLIP2 | c.801C>A p.T267= | Splice Region (SNP) | VAF 50/116 reads (43%) | catalogued as COSV99792271; called by muse, mutect2, varscan2
- CPNE9 | c.1375G>A p.V459I | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.573); catalogued as rs566993609, COSV56067862; called by muse, mutect2, varscan2
- DNMT3A | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 32/69 reads (46%) | catalogued as rs776841024, COSV53039606, COSV99264553; called by muse, mutect2, varscan2
- DSP | c.4627G>T p.E1543* | Nonsense Mutation (SNP) | VAF 38/94 reads (40%) | catalogued as COSV101131768; called by muse, mutect2, varscan2
- H4C7 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV99769278; called by muse, mutect2, varscan2
- IL18R1 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1375262202, COSV52126412, COSV99295491; called by muse, mutect2, varscan2
- KRT1 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as rs748024312, COSV99359004; called by muse, mutect2, varscan2
- LYG2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs781622268, COSV100283487; called by muse, mutect2, varscan2
- MDH1B | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200965288, COSV65590474; called by muse, mutect2, varscan2
- MID2 | c.374C>G p.T125S | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); catalogued as COSV99465627; called by muse, mutect2, varscan2
- MSLN | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs372994754; called by muse, mutect2, varscan2
- PDE8A | c.2126G>A p.R709K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs763577895, COSV100052366; called by muse, mutect2, varscan2
- PKD1L2 | c.1097T>C p.V366A | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100450317; called by muse, mutect2, varscan2
- PRPF8 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517915, COSV59267232; called by muse, mutect2, varscan2
- RANBP2 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs544178123, COSV99313278; called by muse, mutect2
- SOHLH1 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs377353048; called by muse, mutect2, varscan2
- TMC5 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.494); catalogued as COSV101196876; called by muse, mutect2, varscan2
- TRIM38 | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100837645; called by muse, mutect2, varscan2
- XKR4 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV59320259; called by muse, mutect2, varscan2
- ZNF808 | c.1486T>C p.S496P | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100708218, COSV63121924; called by muse, mutect2, varscan2
- CCT6A | c.1073_1077del p.E358Vfs*5 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by pindel, varscan2
- PPP2R2D | c.1173del p.S391Rfs*76 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- TNIK | c.255del p.Y86Mfs*19 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- ADCY4 | c.3006G>A p.P1002= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs757144908, COSV100156600; called by muse, mutect2, varscan2
- CYP7B1 | c.960C>T p.D320= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV59587784; called by muse, mutect2, varscan2
- FADS6 | c.939C>G p.L313= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100044420, COSV59603828; called by muse, mutect2, varscan2
- FRG2B | c.138C>T p.T46= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs755474323, COSV101423544; called by muse, mutect2, varscan2
- LAMA1 | c.2091C>T p.A697= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1435476556, COSV101057733; called by mutect2, varscan2
- MEGF8 | c.6570C>T p.N2190= (on ENST00000251268 / NM_001271938.2; = p.N2123= on NM_001410.3) | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs767893103, COSV99238153; called by muse, mutect2, varscan2
- POTEM | c.372C>T p.D124= | Silent (SNP) | VAF 49/82 reads (60%) | catalogued as rs746497374, COSV69152769; called by muse, mutect2, varscan2
- SHLD2 | c.2340C>T p.V780= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs775413512, COSV100079526; called by muse, mutect2, varscan2
- SMPDL3B | c.1359C>T p.L453= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs757556750, COSV100874612; called by muse, mutect2, varscan2
- SYT3 | c.1182G>A p.R394= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100143770; called by muse, mutect2
- UNC45B | c.1284A>T p.A428= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV99269255; called by muse, mutect2, varscan2
- DUSP13 | c.*885C>T | 3'UTR (SNP) | VAF 15/38 reads (39%) | catalogued as rs141915692, COSV100403448, COSV100403828; called by muse, mutect2, varscan2
- PRND | chr20:4732612 T>A | 3'Flank (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- SNORD116-8 | n.66A>G | RNA (SNP) | VAF 89/221 reads (40%) | called by muse, mutect2, varscan2
